Somatic mutation profile of tumor specimen TCGA-78-7161-01A (aliquot TCGA-78-7161-01A-11D-2036-08) from TCGA case TCGA-78-7161, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 69.3 years (25,294 days).
Specimen TCGA-78-7161-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5e1e9429-dfc2-47b0-963d-9b3152864ee8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-78-7161-10A (Blood Derived Normal), aliquot TCGA-78-7161-10A-01D-2036-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c1448109-b5b1-40cb-9427-099322af712f

The open-access MAF lists 204 somatic variants for this specimen: 146 protein-altering or splice-affecting, 51 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 131, Silent 51, Frame Shift Del 6, Nonsense Mutation 4, Splice Site 3, RNA 3, 3'UTR 1, 5'Flank 1, 3'Flank 1, Nonstop Mutation 1, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 6/15 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- RAD50 | c.205G>T p.D69Y | Missense Mutation (SNP) | VAF 24/34 reads (71%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54748170; called by muse, mutect2, varscan2
- ZIC3 | c.968C>T p.T323M | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs122462165, CM971601, COSV54975789; ClinVar: pathogenic; called by muse, mutect2
- ABCC8 | c.1537G>T p.A513S | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV56854953, COSV56856905; called by muse, mutect2, varscan2
- ADAL | c.310C>A p.L104I | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV67501094; called by muse, mutect2, varscan2
- ADAM19 | c.116C>A p.P39H | Missense Mutation (SNP) | VAF 48/96 reads (50%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.866); catalogued as COSV57435727; called by muse, mutect2, varscan2
- ADAMTS20 | c.1853G>T p.R618L | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67126374, COSV67136307; called by muse, mutect2, varscan2
- ADAMTS6 | c.1155G>C p.R385S | Missense Mutation (SNP) | VAF 29/38 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV101124555, COSV66862833; called by muse, mutect2, varscan2
- AFAP1 | c.1247A>T p.Q416L | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.053); catalogued as COSV61797585; called by muse, mutect2, varscan2
- AKAP17A | c.19G>C p.V7L | Missense Mutation (SNP) | VAF 67/213 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58311227; called by muse, mutect2, varscan2
- ALMS1 | c.7432T>G p.S2478A | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52517212; called by muse, mutect2, varscan2
- AMACR | c.477G>T p.M159I | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.02); catalogued as COSV59462262; called by muse, mutect2, varscan2
- ARHGEF6 | c.294G>T p.K98N | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.947); catalogued as COSV51694250; called by muse, mutect2, varscan2
- ASH2L | c.1121G>T p.R374I | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV51700945; called by muse, mutect2, varscan2
- ASXL3 | c.6283G>A p.E2095K | Missense Mutation (SNP) | VAF 53/96 reads (55%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.452); catalogued as COSV52474264; called by muse, mutect2, varscan2
- ASXL3 | c.6641C>T p.S2214F | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV52474280; called by muse, mutect2
- BCKDHB | c.587A>C p.H196P | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV57516748; called by muse, mutect2, varscan2
- BIRC6 | c.7468G>T p.D2490Y | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs141491090; called by muse, mutect2
- BNC2 | c.2948G>T p.G983V | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.998); catalogued as rs1330774623, COSV66171716; called by muse, mutect2, varscan2
- C1QB | c.95C>A p.P32H | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV100152689; called by muse, mutect2, varscan2
- CELSR3 | c.2272A>G p.M758V | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV50901139; called by muse, mutect2, varscan2
- CFP | c.269C>T p.S90L | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1476877032, COSV55949750; called by muse, mutect2
- CLCN3 | c.1966G>T p.D656Y | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV61628060; called by muse, mutect2, varscan2
- CNBD1 | c.88A>T p.N30Y | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.135); catalogued as COSV72917343; called by muse, mutect2, varscan2
- CNTNAP2 | c.1477G>T p.G493C | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62229296; called by muse, mutect2, varscan2
- COL10A1 | c.392C>A p.P131Q | Missense Mutation (SNP) | VAF 22/28 reads (79%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.99); catalogued as COSV54573983; called by muse, mutect2, varscan2
- COL3A1 | c.745-2A>T p.X249_splice | Splice Site (SNP) | VAF 4/11 reads (36%) | catalogued as COSV58593826; called by muse, mutect2
- CSMD1 | c.10659G>T p.R3553S (on ENST00000520002; = p.R3552S on NM_033225.6) | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0); PolyPhen benign (0.324); catalogued as COSV59358178; called by muse, mutect2, varscan2
- CSMD2 | c.9184C>A p.L3062M | Missense Mutation (SNP) | VAF 49/101 reads (49%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.673); catalogued as COSV53941128; called by muse, mutect2, varscan2
- CSMD3 | c.326C>A p.S109* | Nonsense Mutation (SNP) | VAF 27/95 reads (28%) | catalogued as COSV52104909, COSV99824995; called by muse, mutect2, varscan2
- DEFA5 | c.102G>T p.Q34H | Missense Mutation (SNP) | VAF 64/76 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57962038, COSV57962406; called by muse, mutect2, varscan2
- DMD | c.5263C>A p.P1755T | Missense Mutation (SNP) | VAF 51/93 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.444); catalogued as rs1057515872, COSV63778029; called by muse, mutect2, varscan2
- DNAH17 | c.3835C>A p.L1279M | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101101352; called by muse, mutect2, varscan2
- DNAI4 | c.1028C>T p.S343L | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as COSV64022941; called by muse, mutect2
- DOCK11 | c.1846C>A p.Q616K | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.94); PolyPhen benign (0.017); catalogued as COSV52244563; called by muse, mutect2, varscan2
- DOCK7 | c.3664A>T p.S1222C (on ENST00000635253 / NM_001367561.1; = p.S1191C on NM_033407.3) | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.548); catalogued as COSV52015762; called by muse, mutect2, varscan2
- DSC3 | c.1383T>A p.H461Q | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as COSV64574372; called by muse, mutect2, varscan2
- DSG3 | c.1613T>G p.V538G | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.09); catalogued as COSV57128352; called by muse, mutect2, varscan2
- EXPH5 | c.2175A>T p.E725D | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.149); catalogued as COSV56206041; called by muse, mutect2, varscan2
- FAM13C | c.324G>T p.Q108H | Missense Mutation (SNP) | VAF 51/77 reads (66%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.808); catalogued as COSV53248968, COSV53253044; called by muse, mutect2, varscan2
- FAM83A | c.238T>A p.C80S | Missense Mutation (SNP) | VAF 44/85 reads (52%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV52686759; called by muse, mutect2, varscan2
- FASN | c.7520del p.S2507Tfs*33 | Frame Shift Del (DEL) | VAF 6/45 reads (13%) | catalogued as COSV60750553; called by mutect2, pindel, varscan2
- FRMD6 | c.362G>C p.R121T (on ENST00000344768 / NM_001267046.2; = p.R113T on NM_152330.4) | Missense Mutation (SNP) | VAF 56/253 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.092); catalogued as COSV61089936; called by muse, mutect2, varscan2
- GABRG1 | c.1322C>G p.S441C | Missense Mutation (SNP) | VAF 57/84 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV54958964, COSV99778198; called by muse, mutect2, varscan2
- GDF10 | c.40C>A p.P14T | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as rs1555206740; called by muse, mutect2, varscan2
- GRM7 | c.2557G>C p.E853Q | Missense Mutation (SNP) | VAF 45/69 reads (65%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.968); catalogued as COSV63158798; called by muse, mutect2, varscan2
- GTF2E1 | c.1003G>C p.A335P | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV52205605; called by muse, mutect2, varscan2
- HDC | c.782C>A p.P261H | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV51076363; called by muse, mutect2, varscan2
- HSPG2 | c.1334G>T p.G445V | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65930638; called by muse, mutect2, varscan2
- IFNE | c.574C>T p.P192S | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0.005); catalogued as COSV58642913; called by muse, mutect2, varscan2
- ITFG2 | c.841C>G p.L281V | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57390425; called by muse, varscan2
- KIAA1755 | c.1147T>A p.C383S | Missense Mutation (SNP) | VAF 84/151 reads (56%) | SIFT tolerated (0.38); PolyPhen benign (0.025); catalogued as COSV54079118; called by muse, mutect2, varscan2
- KIF5A | c.1922G>T p.R641L | Missense Mutation (SNP) | VAF 24/173 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.115); catalogued as COSV54057307; called by muse, mutect2, varscan2
- KLHL14 | c.814C>A p.P272T | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.92); catalogued as COSV63834438; called by muse, mutect2, varscan2
- KRT79 | c.1243C>A p.L415M | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57941521; called by muse, mutect2, varscan2
- LAMA4 | c.2183A>C p.Q728P (on ENST00000230538 / NM_001105206.3; = p.Q721P on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV57902316; called by muse, mutect2, varscan2
- LGALS4 | c.719G>A p.R240H | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs371360675; called by muse, mutect2, varscan2
- LRRC7 | c.665C>A p.A222D (on ENST00000651989 / NM_001370785.2; = p.A189D on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.686); catalogued as rs755151095, COSV50543518, COSV99229145; called by muse, mutect2, varscan2
- LRRC7 | c.3233T>A p.V1078E (on ENST00000651989 / NM_001370785.2; = p.V1045E on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.271); catalogued as COSV50543730; called by muse, mutect2, varscan2
- LRRC8D | c.275G>C p.G92A | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV61580535; called by muse, mutect2
- MAGEH1 | c.77A>G p.Q26R | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.876); catalogued as rs1359408710, COSV61678980; called by muse, mutect2, varscan2
- MBD5 | c.1609A>T p.S537C | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV68698446; called by muse, mutect2, varscan2
- MTHFD2 | c.938G>A p.G313D | Missense Mutation (SNP) | VAF 28/139 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51202108; called by muse, mutect2, varscan2
- MUC16 | c.25743G>T p.E8581D | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as COSV67481475; called by muse, mutect2, varscan2
- NEB | c.2003G>C p.R668T | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT tolerated (0.35); PolyPhen benign (0.273); catalogued as rs1430285423, COSV51442075; called by muse, mutect2, varscan2
- NPAP1 | c.199G>T p.A67S | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.164); catalogued as rs1404920860, COSV61506709, COSV61509654; called by muse, mutect2, varscan2
- NPC1L1 | c.2176C>T p.R726W | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.293); catalogued as rs149392392; called by muse, mutect2, varscan2
- NT5DC1 | c.230A>C p.K77T | Missense Mutation (SNP) | VAF 30/37 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60310687; called by muse, mutect2, varscan2
- OR2A42 | c.169C>A p.P57T | Missense Mutation (SNP) | VAF 16/18 reads (89%) | SIFT deleterious (0); PolyPhen benign (0.327); catalogued as COSV101195810; called by mutect2, varscan2
- OR2AK2 | c.137T>G p.I46S | Missense Mutation (SNP) | VAF 86/221 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.114); catalogued as COSV63558003; called by muse, mutect2, varscan2
- OR2L2 | c.331G>A p.G111R | Missense Mutation (SNP) | VAF 73/120 reads (61%) | SIFT tolerated (0.21); PolyPhen benign (0.066); catalogued as COSV63558007; called by muse, mutect2, varscan2
- OR2T33 | c.212T>A p.L71Q | Missense Mutation (SNP) | VAF 8/161 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV58816877; called by muse, mutect2
- OR5M10 | c.135G>T p.M45I | Missense Mutation (SNP) | VAF 46/63 reads (73%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV73242395; called by muse, mutect2, varscan2
- OR8K1 | c.83G>A p.G28E | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs762372416, COSV54401578, COSV99687245; called by muse, mutect2, varscan2
- PAK3 | c.513G>C p.S171= (on ENST00000262836 / NM_001324328.2; = p.S156= on NM_002578.5 and 4 other RefSeq transcripts) | Splice Region (SNP) | VAF 10/46 reads (22%) | catalogued as COSV53278195; called by muse, mutect2, varscan2
- PAK3 | c.1164A>T p.Q388H (on ENST00000262836 / NM_001324328.2; = p.Q373H on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.877); catalogued as COSV53273794; called by muse, mutect2, varscan2
- PAPPA | c.3032G>A p.C1011Y | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60288946; called by mutect2, varscan2
- PAX7 | c.1184C>T p.A395V | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as rs761460050, COSV64751693; called by muse, mutect2, varscan2
- PCDH11X | c.4001C>A p.P1334Q | Missense Mutation (SNP) | VAF 26/159 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.027); catalogued as COSV100009965, COSV53445042, COSV53490727; called by muse, mutect2, varscan2
- PCDHB15 | c.1798G>A p.A600T | Missense Mutation (SNP) | VAF 37/154 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV99178801; called by muse, mutect2, varscan2
- PCDHGA11 | c.2194G>T p.G732W | Missense Mutation (SNP) | VAF 39/124 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.858); catalogued as COSV53912125, COSV54010412; called by muse, mutect2, varscan2
- PCNT | c.3465-1G>T p.X1155_splice | Splice Site (SNP) | VAF 30/71 reads (42%) | catalogued as COSV64031300; called by muse, mutect2, varscan2
- PELO | c.334C>G p.L112V | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.498); catalogued as COSV50891229; called by muse, mutect2, varscan2
- PHKA1 | c.2093A>T p.D698V | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as rs368443920, COSV59809106; called by muse, mutect2, varscan2
- PHLPP2 | c.31A>C p.N11H | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV62426294; called by muse, mutect2, varscan2
- PKN1 | c.1381C>T p.Q461* | Nonsense Mutation (SNP) | VAF 11/34 reads (32%) | catalogued as COSV99660665; called by muse, mutect2, varscan2
- PLCB2 | c.1957G>T p.G653C | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53036310; called by muse, mutect2, varscan2
- PLXNB1 | c.2609C>T p.S870L | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); catalogued as COSV56492590; called by muse, mutect2, varscan2
- PNPLA8 | c.694G>T p.D232Y | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT deleterious (0.05); PolyPhen benign (0.232); catalogued as COSV57552571; called by muse, mutect2, varscan2
- PPFIBP2 | c.594G>T p.Q198H | Missense Mutation (SNP) | VAF 44/84 reads (52%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.51); catalogued as COSV55080525; called by muse, mutect2, varscan2
- PPP1R13B | c.2101G>A p.A701T | Missense Mutation (SNP) | VAF 7/152 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1315422706, COSV52454551; called by muse, mutect2
- RAI2 | c.703C>A p.P235T | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV58965709; called by muse, mutect2, varscan2
- RBM48 | c.11G>T p.S4I | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.317); catalogued as COSV50408469; called by muse, mutect2, varscan2
- RLF | c.1306C>T p.P436S | Missense Mutation (SNP) | VAF 90/174 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV65652684; called by muse, mutect2, varscan2
- RYR2 | c.4812G>T p.L1604F | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV63702839; called by muse, mutect2, varscan2
- SAMD14 | c.163G>A p.A55T | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.227); catalogued as COSV53310778; called by muse, mutect2, varscan2
- SBF1 | c.2945A>T p.Q982L | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100817402; called by muse, mutect2
- SCPEP1 | c.1357T>C p.*453Qext*7 | Nonstop Mutation (SNP) | VAF 24/116 reads (21%) | catalogued as COSV51855140; called by muse, mutect2, varscan2
- SERGEF | c.871C>T p.R291* | Nonsense Mutation (SNP) | VAF 6/37 reads (16%) | catalogued as rs779355909, COSV56386056; called by muse, mutect2, varscan2
- SFXN5 | c.230C>T p.P77L | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as rs757794407, COSV55586072; called by mutect2, varscan2
- SLC10A5 | c.10A>G p.K4E | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV72828441; called by muse, mutect2, varscan2
- SLC25A32 | c.155-1G>T p.X52_splice | Splice Site (SNP) | VAF 51/92 reads (55%) | catalogued as COSV52568663; called by muse, mutect2, varscan2
- SLC25A33 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 36/48 reads (75%) | SIFT tolerated (0.57); PolyPhen benign (0.065); catalogued as rs1247875365, COSV57021299; called by muse, mutect2, varscan2
- SLC39A12 | c.1934C>T p.S645F (on ENST00000377369 / NM_001145195.2; = p.S608F on NM_152725.3) | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs752678532, COSV66201171; called by muse, mutect2, varscan2
- SLC5A4 | c.204G>T p.W68C | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.254); catalogued as COSV99831622; called by muse, mutect2, varscan2
- SLC5A4 | c.203G>T p.W68L | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.12); catalogued as COSV99831625; called by muse, mutect2, varscan2
- SLC6A18 | c.343T>C p.Y115H | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57253206, COSV57253825; called by muse, mutect2, varscan2
- SLC8A3 | c.900C>G p.N300K | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated (0.79); PolyPhen benign (0.101); catalogued as rs1264287902, COSV63524784, COSV63527524; called by muse, mutect2, varscan2
- SLC9A4 | c.2333C>A p.T778K | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT deleterious (0.05); PolyPhen benign (0.025); catalogued as COSV54837198; called by muse, mutect2, varscan2
- SLITRK3 | c.895T>A p.S299T | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.023); catalogued as COSV53851440; called by muse, mutect2, varscan2
- SPATA31E1 | c.2768C>A p.P923Q | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV57795145; called by muse, mutect2, varscan2
- SPRR2G | c.88C>A p.P30T | Missense Mutation (SNP) | VAF 81/171 reads (47%) | PolyPhen possibly damaging (0.714); catalogued as COSV64203284; called by muse, mutect2, varscan2
- SSU72P8 | c.398C>A p.P133H | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66361286; called by muse, mutect2, varscan2
- SYTL4 | c.411G>C p.R137S | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV52170087; called by muse, mutect2, varscan2
- TAAR6 | c.880G>T p.E294* | Nonsense Mutation (SNP) | VAF 73/94 reads (78%) | catalogued as COSV51584474; called by muse, mutect2, varscan2
- TBL1X | c.1692C>A p.S564R | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.988); catalogued as rs867158698, COSV54285293; called by muse, mutect2, varscan2
- TDRD10 | c.506G>T p.G169V | Missense Mutation (SNP) | VAF 118/332 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV52726408; called by muse, mutect2, varscan2
- TEAD4 | c.628C>T p.P210S | Missense Mutation (SNP) | VAF 41/66 reads (62%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV63281953; called by muse, mutect2, varscan2
- TMTC4 | c.1767C>G p.N589K (on ENST00000376234 / NM_001350577.2; = p.N608K on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60893178; called by muse, mutect2, varscan2
- TPP1 | c.119G>C p.R40P | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.325); catalogued as COSV54999153; called by muse, mutect2, varscan2
- TRANK1 | c.3748G>A p.E1250K | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.696); catalogued as COSV57159184; called by muse, mutect2, varscan2
- TRIM51 | c.715A>G p.K239E | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV55269231; called by muse, mutect2, varscan2
- TRIT1 | c.992A>C p.N331T | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as COSV57549437; called by muse, mutect2, varscan2
- TRO | c.3164C>A p.T1055N | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.13); catalogued as COSV51505256; called by muse, mutect2, varscan2
- TRPC1 | c.611A>G p.K204R (on ENST00000476941 / NM_001251845.2; = p.K170R on NM_003304.4) | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT tolerated (0.28); PolyPhen benign (0.137); catalogued as COSV56428034; called by muse, mutect2, varscan2
- TRPM6 | c.2305T>C p.S769P | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); catalogued as COSV62518367; called by muse, varscan2
- TRPS1 | c.288C>A p.N96K (on ENST00000220888 / NM_001330599.2; = p.N109K on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/151 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.023); catalogued as COSV55254452; called by muse, mutect2, varscan2
- TTN | c.46910C>A p.T15637N (on ENST00000591111; = p.T8213N on NM_003319.4) | Missense Mutation (SNP) | VAF 27/62 reads (44%) | PolyPhen benign (0.173); catalogued as COSV60231292; called by muse, mutect2, varscan2
- USH2A | c.14396C>A p.T4799N | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as COSV56408800, COSV56412222; called by muse, mutect2, varscan2
- VGLL2 | c.16G>A p.V6I | Missense Mutation (SNP) | VAF 26/34 reads (76%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV58310370; called by muse, mutect2, varscan2
- VHLL | c.77G>A p.C26Y | Missense Mutation (SNP) | VAF 49/138 reads (36%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.104); catalogued as rs756377054, COSV60554554; called by muse, mutect2, varscan2
- VN1R2 | c.355T>A p.Y119N | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT tolerated (0.21); PolyPhen benign (0.246); catalogued as COSV59039187; called by muse, mutect2, varscan2
- VSNL1 | c.448C>G p.R150G | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54602029; called by muse, mutect2, varscan2
- WWP1 | c.61C>G p.Q21E | Missense Mutation (SNP) | VAF 32/135 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.297); catalogued as COSV55362369; called by muse, mutect2, varscan2
- WWP1 | c.154A>G p.K52E | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV55362375; called by muse, mutect2
- ZC3H3 | c.1775G>A p.G592D | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.03); catalogued as COSV52792958; called by muse, mutect2
- ZMYM5 | c.269A>G p.E90G | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV61989337; called by muse, mutect2, varscan2
- ZNF234 | c.1312C>T p.R438C | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.825); catalogued as rs1050998717, COSV70603787; called by muse, mutect2, varscan2
- ZNF676 | c.97A>T p.M33L (on ENST00000650058; = p.M1? on NM_001001411.3) | Missense Mutation (SNP) | VAF 68/91 reads (75%) | SIFT deleterious (0.03); PolyPhen benign (0.14); catalogued as COSV68094243; called by muse, mutect2, varscan2
- ZP4 | c.349C>A p.H117N | Missense Mutation (SNP) | VAF 185/290 reads (64%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV100850579, COSV63912987; called by muse, mutect2, varscan2
- PKHD1L1 | c.4655del p.N1552Ifs*17 | Frame Shift Del (DEL) | VAF 10/54 reads (19%) | called by mutect2, pindel, varscan2
- PLXNB3 | c.4028del p.P1343Lfs*68 | Frame Shift Del (DEL) | VAF 17/76 reads (22%) | called by mutect2, pindel, varscan2
- SUPT20HL2 | c.1105C>A p.P369T | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- SYNM | c.4325del p.A1442Efs*7 | Frame Shift Del (DEL) | VAF 102/280 reads (36%) | called by mutect2, pindel, varscan2
- XKR7 | c.972del p.Y324* | Frame Shift Del (DEL) | VAF 10/49 reads (20%) | called by mutect2, pindel, varscan2
- XRCC2 | c.350del p.L117Wfs*17 | Frame Shift Del (DEL) | VAF 6/48 reads (13%) | called by mutect2, varscan2
- ACACA | c.514C>A p.R172= | Silent (SNP) | VAF 15/62 reads (24%) | called by muse, mutect2, varscan2
- ADAMTS13 | c.2142C>T p.A714= | Silent (SNP) | VAF 12/83 reads (14%) | catalogued as COSV63022475; called by muse, mutect2, varscan2
- AMOTL1 | c.864C>T p.F288= | Silent (SNP) | VAF 20/181 reads (11%) | catalogued as COSV100133624; called by muse, varscan2
- ARHGAP26 | c.1641C>T p.I547= | Silent (SNP) | VAF 42/130 reads (32%) | catalogued as COSV50832011, COSV50832662, COSV50836679; called by muse, mutect2, varscan2
- ASXL3 | c.6639C>T p.C2213= | Silent (SNP) | VAF 32/63 reads (51%) | catalogued as rs201578514, COSV52474273; called by muse, mutect2
- ATP2B3 | c.228T>C p.N76= | Silent (SNP) | VAF 34/56 reads (61%) | catalogued as rs1557006175, COSV54856323; called by muse, mutect2, varscan2
- C1QB | c.96C>A p.P32= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV100152693; called by muse, mutect2, varscan2
- CBLIF | c.1038C>A p.V346= | Silent (SNP) | VAF 46/106 reads (43%) | catalogued as COSV57239893; called by muse, mutect2, varscan2
- CDH23 | c.3150C>A p.A1050= | Silent (SNP) | VAF 49/77 reads (64%) | catalogued as rs764006222, COSV54924170, COSV54945568; called by muse, mutect2, varscan2
- CINP | c.246G>T p.L82= | Silent (SNP) | VAF 62/102 reads (61%) | catalogued as COSV53737130; called by muse, mutect2, varscan2
- COL2A1 | c.3759C>T p.A1253= | Silent (SNP) | VAF 21/102 reads (21%) | catalogued as rs761840345, COSV61532724; called by muse, mutect2, varscan2
- CTNNA2 | c.1395C>A p.A465= | Silent (SNP) | VAF 15/38 reads (39%) | catalogued as COSV58153061; called by muse, mutect2, varscan2
- CYLD | c.2805A>G p.A935= | Silent (SNP) | VAF 20/52 reads (38%) | catalogued as COSV61096441; called by muse, mutect2, varscan2
- DCAF12L2 | c.1056C>A p.G352= | Silent (SNP) | VAF 16/94 reads (17%) | catalogued as COSV63583524; called by muse, mutect2, varscan2
- DPYSL4 | c.1621C>T p.L541= | Silent (SNP) | VAF 78/117 reads (67%) | catalogued as COSV53843742; called by muse, mutect2, varscan2
- DYNC1I1 | c.1845T>C p.N615= | Silent (SNP) | VAF 42/79 reads (53%) | catalogued as COSV61463133; called by muse, mutect2, varscan2
- EPS8L3 | c.696C>A p.P232= | Silent (SNP) | VAF 46/148 reads (31%) | catalogued as COSV62610147; called by muse, mutect2, varscan2
- FAM171A1 | c.171C>T p.F57= | Silent (SNP) | VAF 29/80 reads (36%) | catalogued as COSV65316452; called by muse, mutect2, varscan2
- GRAMD1B | c.1863C>A p.S621= | Silent (SNP) | VAF 10/14 reads (71%) | catalogued as COSV59208589; called by muse, varscan2
- HPS5 | c.2940C>T p.C980= (on ENST00000349215 / NM_181507.2; = p.C866= on NM_007216.4) | Silent (SNP) | VAF 22/33 reads (67%) | catalogued as COSV61687812; called by muse, mutect2, varscan2
- ITFG2 | c.945C>T p.V315= | Silent (SNP) | VAF 50/140 reads (36%) | catalogued as COSV57390443; called by muse, mutect2, varscan2
- ITGA8 | c.1485G>A p.L495= | Silent (SNP) | VAF 63/137 reads (46%) | catalogued as COSV100959130, COSV65233185; called by muse, mutect2, varscan2
- KCTD10 | c.282G>T p.G94= | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as COSV99949026; called by muse, mutect2, varscan2
- KIAA0586 | c.3963G>T p.V1321= (on ENST00000619416 / NM_001244190.2; = p.V1260= on NM_014749.5) | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as COSV54180005; called by muse, mutect2, varscan2
- KIAA1109 | c.12381C>T p.G4127= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as COSV52685575; called by muse, mutect2, varscan2
- KPRP | c.942T>A p.I314= | Silent (SNP) | VAF 75/124 reads (60%) | catalogued as COSV64222510; called by muse, mutect2, varscan2
- LPIN2 | c.2259C>T p.D753= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as rs1203271254, COSV55242437; called by muse, mutect2
- LRP1B | c.13614G>A p.P4538= | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as rs758111549, COSV67225869; called by muse, mutect2, varscan2
- MRPS27 | c.36G>T p.L12= | Silent (SNP) | VAF 25/33 reads (76%) | catalogued as COSV54652692; called by muse, mutect2, varscan2
- MUC16 | c.8841C>A p.A2947= | Silent (SNP) | VAF 18/89 reads (20%) | catalogued as COSV67481480; called by muse, mutect2, varscan2
- NAT10 | c.633C>T p.S211= | Silent (SNP) | VAF 38/79 reads (48%) | catalogued as COSV57665499; called by muse, mutect2, varscan2
- NEB | c.336A>G p.P112= | Silent (SNP) | VAF 51/146 reads (35%) | catalogued as COSV51442093, COSV99426278; called by muse, mutect2, varscan2
- NELFCD | c.1386G>A p.A462= (on ENST00000602795; = p.A444= on NM_198976.4) | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as rs141996345; called by muse, mutect2, varscan2
- NLGN3 | c.522C>A p.S174= (on ENST00000358741 / NM_181303.2; = p.S154= on NM_018977.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV62443634, COSV62444634; called by muse, mutect2, varscan2
- NMS | c.180T>G p.P60= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as COSV65259081; called by muse, mutect2, varscan2
- OR4N2 | c.294C>A p.I98= | Silent (SNP) | VAF 111/182 reads (61%) | catalogued as COSV60053629; called by muse, mutect2, varscan2
- PCDHGA1 | c.825G>T p.G275= | Silent (SNP) | VAF 24/64 reads (38%) | catalogued as COSV65298353; called by muse, mutect2, varscan2
- PCDHGA2 | c.777C>A p.T259= | Silent (SNP) | VAF 60/160 reads (38%) | catalogued as rs1220367601, COSV53999870; called by muse, mutect2, varscan2
- PIGT | c.1098G>T p.G366= | Silent (SNP) | VAF 28/69 reads (41%) | catalogued as COSV54127730; called by muse, mutect2, varscan2
- PKN1 | c.1380G>C p.V460= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as COSV99660809; called by muse, mutect2, varscan2
- PLEKHG2 | c.1479A>T p.P493= | Silent (SNP) | VAF 12/21 reads (57%) | catalogued as COSV52687368; called by muse, mutect2, varscan2
- PRUNE2 | c.3198C>T p.S1066= | Silent (SNP) | VAF 18/56 reads (32%) | catalogued as COSV65044986; called by muse, mutect2, varscan2
- PSG7 | c.198C>A p.I66= | Silent (SNP) | VAF 122/231 reads (53%) | catalogued as rs781815812, COSV68445323, COSV68446039; called by muse, mutect2, varscan2
- SCN10A | c.4917C>T p.D1639= | Silent (SNP) | VAF 36/142 reads (25%) | catalogued as rs142804903; called by muse, mutect2, varscan2
- TENM1 | c.7311A>G p.Q2437= | Silent (SNP) | VAF 39/217 reads (18%) | catalogued as rs185102844, COSV64438838; called by muse, mutect2, varscan2
- USP35 | c.960C>T p.P320= | Silent (SNP) | VAF 16/146 reads (11%) | catalogued as rs1448675125, COSV71573116; called by muse, mutect2, varscan2
- UVSSA | c.607C>T p.L203= | Silent (SNP) | VAF 20/57 reads (35%) | catalogued as COSV66230531; called by muse, mutect2, varscan2
- ZNF432 | c.1419T>C p.I473= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV55416148; called by muse, mutect2, varscan2
- ZNF480 | c.1530T>G p.P510= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV57997430; called by muse, mutect2, varscan2
- ZNF676 | c.897C>A p.T299= (on ENST00000650058; = p.T267= on NM_001001411.3) | Silent (SNP) | VAF 31/42 reads (74%) | catalogued as COSV101236126, COSV68093012; called by muse, mutect2, varscan2
- ZNF800 | c.1683A>T p.I561= | Silent (SNP) | VAF 30/65 reads (46%) | catalogued as COSV56178575, COSV56178810; called by muse, mutect2, varscan2
- AC024940.1 | n.3395T>A | RNA (SNP) | VAF 39/96 reads (41%) | called by muse, mutect2, varscan2
- ECPAS | chr9:111484388 A>G | 5'Flank (SNP) | VAF 8/23 reads (35%) | catalogued as rs757583361, COSV52203991; called by muse, mutect2, varscan2
- LCE1B | c.*1A>T | 3'UTR (SNP) | VAF 76/150 reads (51%) | catalogued as COSV100780249; called by muse, mutect2, varscan2
- PSG5 | c.431-2999C>A | Intron (SNP) | VAF 75/170 reads (44%) | catalogued as COSV100742554; called by muse, mutect2
- RN7SL484P | chr15:99792435 G>A | 3'Flank (SNP) | VAF 36/179 reads (20%) | called by muse, mutect2, varscan2
- SSPOP | n.10929G>T | RNA (SNP) | VAF 24/56 reads (43%) | catalogued as COSV65134374; called by muse, mutect2, varscan2
- TCP10L3 | n.2533G>T | RNA (SNP) | VAF 9/21 reads (43%) | catalogued as COSV64751069, COSV64752128; called by muse, mutect2, varscan2
